Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAF8, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAF8-01A (Primary Tumor).

Department of Pathology

ICD-O-3
Seminoma NOS 9061/3
Site ① Testis NOS C62.9
W 01/14

Direct dial

Mobile:

Internal postal address

E-mai

Date

Concerning

Summary pathology report

Left orchidectomy; seminoma; diameter 3.5 cm; tumor confined to testis in available slides; no angio-invasion; no invasion in rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 3ed854d5-c8fd-4fc7-abdf-545657057143 (TCGA-2G-AAF8.0174DE5A-8AFD-4FBB-8509-19BD0F2B3FFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).